Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EI, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EI-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD-O-3
Liposarcoma dedifferentiated
8858/3
Site Retroperitoneum C48.0
Date 9/26/13

Clinical Diagnosis & History:

[REDACTED] with left retroperitoneal mass. Bx c/w high grade spindle cell neoplasm.

Specimens Submitted:

- 1: SP: Retroperitoneal dissection with lt. colon, lt. kidney
- 2: SP: Lt. psoas mass
- 3: SP: Left common iliac lymph node

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEAL DISSECTION WITH LEFT COLON, LEFT KIDNEY AND SEGMENT OF

DUODENUM; RESECTION:

- DEDIFFERENTIATED LIPOSARCOMA WITH DIVERGENT DIFFERENTIATION (HIGH GRADE LEIOMYOSARCOMA).
- TWO TUMOR FOCI, 6.0 CM AND 3.0 CM IN GREATEST DIMENSION RESPECTIVELY.
- TUMOR EXTENDS FOCALLY TO INKED MARGIN.
- TUMOR INVOLVES THE PERINEPHRIC ADIPOSE TISSUE, OMENTAL TISSUE AND SUBSEROZA OF

DUODENUM.

- COLONIC DIVERTICULOSIS.
- UNREMARKABLE KIDNEY PARENCHYMA.
- THE IMMUNOHISTOCHEMICAL STUDY SHOWS THAT THE DIVERGENT DIFFERENTIATED COMPONENT IS POSITIVE FOR DESMIN, CMA AND SMA, AND NEGATIVE FOR C-KIT. THE HISTOLOGIC AND IMMUNOPHENOTYPE OF THIS TUMOR SUPPORT A SMOOTH MUSCLE DIFFERENTIATION FOR THIS COMPONENT.
- NINETEEN BENIGN LYMPH NODES (0/19).

- 2) SOFT TISSUE, LEFT PSOAS MASS; RESECTION:

- DEDIFFERENTIATED LIPOSARCOMA, WITH DIVERGENT DIFFERENTIATION (HIGH GRADE LEIOMYOSARCOMA). AREAS OF LOW GRADE, WELL DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE, WITH FOCAL MYXOID CHANGE AND BONE METAPLASIA ARE ALSO PRESENT.

- THE TUMOR MEASURES 6.5 CM IN GREATEST DIMENSION.
- THE SKELETAL MUSCLE RESECTION MARGIN IS FREE OF TUMOR.
- ONE BENIGN LYMPH NODE (0/1).

- 3) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:

- ONE BENIGN LYMPH NODE (0/1).

PATH
REPORT

** Continued on next page **

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 4
- FIBROADIPOSE TISSUE FOCALLY INFILTRATED BY LOW GRADE LIPOSARCOMA,
SCLEROSING TYPE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
negative	CD117	
positive	des	
positive	CMA (HHF35)	
positive	SMA	
	IMM RECUT	
	NEG CONT	

Gross Description:

1) The specimen is received fresh, labeled "Retroperitoneal Dissection With left Colon, Left Kidney". It consists of a segment of colon measuring 55.0 cm in length and 7.0 cm in greatest diameter with a small amount of mesenteric tissue and pericolic adipose tissue attached. No orientation is given. Adherent to the mesenteric and pericolic adipose tissue are two nodular tumor masses with a focally lobulated surface, measuring 6.0 x 5.5 x 4.0 cm and 3.0 x 3.0 x 1.5 cm, respectively. The larger and smaller nodular tumor masses are connected by a piece of fibrotic mesenteric tissue. Both tumor nodules are partially covered by a fibrotic, mesenteric tissue with focal areas covered only by a thin membranous fibrous tissue. The surface of the two tumor nodules is entirely inked black. The larger tumor nodule is also adherent to a segment of duodenum, which measures 11.0 cm in length and 4.0 cm in diameter. Grossly, the larger tumor mass is adherent to the serosal surface, but not invading into the subserosa of the duodenal segment. The duodenal mucosa is extensively congested with no discrete tumor mass identified. Also received in the container is a kidney measuring 10.5 x 5.0 x 3.0 cm, which has a segment of unremarkable ureter measuring 9.0 cm in length and 0.3 cm in diameter. Upon opening, the renal parenchyma appears unremarkable with the cortical thickness measuring up to 0.4 cm. The smaller tumor mass is adherent to the perinephric adipose tissue and focally abuts, but not invading into the renal capsule. Upon opening the large bowel, it contains a large amount of tan-brown liquid material. The colonic mucosa is markedly flattened with multiple diverticula and no evidence of a discrete tumor mass identified. A lymph node search is performed in the pericolic adipose tissue and multiple lymph nodes are identified, measuring up to 1.3 cm in greatest dimension. A portion of tumor mass is submitted for TPS,

Gross photograph taken. Representative sections are submitted.

PATH
REPORT

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

CM1 one colonic resection margin
CM2 the other colonic resection margin
D - diverticula
UVM renal ureteral and renal hilar vessel resection margins
TK smaller tumor nodule and adjacent renal parenchyma
TRF smaller tumor nodule present in the perinephric adipose tissue
ST small tumor nodule
K representative sections of the renal parenchyma
TD larger tumor nodule and adjacent duodenum
LT larger tumor nodule
LN pericolic lymph nodes

Page 3 of 4

2) The specimen is received fresh, labeled "Left Psoas Mass". It consists of a soft tissue mass, measuring 6.5 x 5.0 x 4.0 cm, which has a multi-lobulated surface and is covered by fibrous tissue and focally skeletal muscle. No orientation is given. The skeletal muscle is designated as a resection margin as per conversation with . The fragment of skeletal muscle is inked black, and the remaining soft tissue surface is inked yellow. The specimen is sequentially sectioned to reveal a tan-white, fleshy cut surface with focal cystic change, central fibrosis and bone formation. The tumor mass appears to be entirely encapsulated by a thin, membranous, fibrous tissue and the skeletal margin grossly appears to be free of tumor. A portion of tumor is submitted for TPS and Gross photograph taken. Representative sections are submitted.

Summary of Sections:

MM skeletal resection margin
T tumor
TD tumor with calcification and bone formation, pending decalcification

3) The specimen is received in formalin, labeled "Left common iliac lymph node ". It consists of a single piece of fibroadipose tissue measuring 1.5 x 1.0 x 0.8 cm. The specimen is bisected and submitted entirely.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Retroperitoneal dissection with lt. colon, lt. kidney

Block	Sect.	Site	PCs
1	CM1		1

PATH
REPORT

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

1	CM2	1
1	D	1
2	K	2
6	LN-M	0
4	LT	4
3	ST	3
2	TD	2
1	TK	1
1	TRF	1
1	UVM	1

Page 4 of 4

Part 2: SP: . psoas mass

Block	Sect.	Site	PCs
2		MM	2
5		T	5
1		TD	2

Part 3: SP: Left common iliac lymph node

Block	Sect.	Site	PCs
1		U	2

PATH
REPORT

** End of Report **

Criteria	hw 8/24/13	Yes	No
H/PAI Discrepancy			✓

Source: NCI Genomic Data Commons file 372bd1cb-195a-4d3a-b29e-66ea0132b527 (TCGA-DX-A7EI.3450A6D6-C088-443C-B703-9FFB63E4A361.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).